Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3KW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3KW-01A (Primary Tumor).

[page 1 of 3]
ICB-0-3
adenocarcinoma, serous, NOS 8441/3
site: endometrium C54.1 lw 12/21/11

Surgical Pathology Consultation Report

Specimen(s) Received

1. Lymph node: Right Pelvic nodes
2. Lymph node: Left pelvic nodes
3. Lymph node: Right obturator node
4. Uterus: Uterus, cervix, ovaries & tubes

Diagnosis

1. Lymph nodes, right pelvic, dissection:
- Six lymph nodes, negative for malignancy (0/6)
2. Lymph nodes, left pelvic, dissection:
- Eleven lymph nodes, negative for malignancy (0/11)
3. Lymph nodes, right obturator, dissection:
- Four lymph nodes, negative for malignancy (0/4)
4. Uterus, cervix, bilateral fallopian tubes and ovaries, total hysterectomy bilateral salpingo-oophorectomy:

Uterus:

SEROUS ADENOCARCINOMA OF ENDOMETRIUM:

- arising in association with endometrial polyp
- superficial extension into inner one half of myometrial thickness
- lymphovascular space involvement not identified
- uninvolved endometrium - atrophic
- cervix- negative for carcinoma

Ovaries:

- Negative for carcinoma

Fallopian tubes:

- Negative for carcinoma

Comment

Immunoprofile:

WT-1, ER - positive
p53, HNF-1 - negative

Synoptic Data

[page 2 of 3]
Surgical Pathology Consultation Report

Specimen:	Uterine corpus Cervix Right ovary Left ovary Right fallopian tube Left fallopian tube
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy
Lymph Node Sampling:	Performed: Pelvic lymph nodes
Specimen Integrity:	Intact hysterectomy specimen
Tumor Size:	Greatest dimension: 3.5 cm Additional dimension: 3.1 cm Additional dimension: 2.8 cm
Histologic Type:	Serous adenocarcinoma
Histologic Grade:	Not applicable
Myometrial Invasion:	Present Myometrial thickness: 10 mm Less than 50% myometrial invasion
Involvement of Cervix:	Not involved
Extent of Involvement of Other Organs:	Right ovary not involved Left ovary not involved Right fallopian tube not involved Left fallopian tube not involved Vagina not applicable Right parametrium not applicable Left parametrium not applicable Omentum not applicable Rectal wall not applicable Bladder wall not applicable Pelvic wall not applicable Bladder mucosa and/or bowel mucosa not applicable
Margins:	Uninvolved by invasive carcinoma
Lymph-Vascular Invasion:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1a (IA): Tumor limited to endometrium or invades less than 1/2 of the myometrium
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Pelvic lymph nodes examined: 21 Pelvic lymph nodes involved: 0 Para-aortic lymph nodes examined: 0 Para-aortic lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None Identified

Gross Description

1. The specimen container labelled with the patient's name and as "right pelvic lymph nodes" contains a single piece of an unoriented fibroadipose tissue measuring 2.1 x 2.2 x 1.4 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified grossly measuring 0.3 x 0.3 x 0.4 cm to 0.7 x 0.4 x 0.4 cm. The specimen is submitted in toto as follows:
1A multiple lymph nodes

[page 3 of 3]
Surgical Pathology Consultation Report

1B the rest of the fatty tissue submitted in toto

2. The specimen container labelled with the patient's name and as "left pelvic lymph nodes" contains 3 pieces of an unoriented fibroadipose tissue measuring 1.3 x 1.8 x 1.4 to 2.4 x 1.8 x 2.4 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified grossly measuring 0.3 x 0.2 x 0.2 cm to 2.1 x 0.5 x 0.4 cm.

The specimen is submitted in toto as follows:

2A one lymph node bisected

2B one lymph node bisected

C. multiple lymph nodes.

2D one lymph node bisected

2E multiple lymph nodes.

2F the rest of the fatty tissue submitted in toto

3. The specimen container labelled with the patient's name and as "right obturator lymph nodes" contains a single piece of an unoriented fibroadipose tissue measuring 3.2 x 1.2 x 0.9 cm received in 10% buffered formalin. Within the fatty tissue, two lymph nodes are identified grossly measuring 1.0 x 0.6 x 0.3 and 2.6 x 0.8 x 0.4 cm.

The specimen is submitted in toto as follows:

3A one lymph node bisected

3B one lymph node bisected

3C the rest of the fatty tissue submitted in toto

4. The specimen container is labeled with the patient's name and as "uterus, cervix ovaries and tubes" contains a uterus with cervix, bilateral fimbriated fallopian tube and bilateral ovaries received in 10% buffered formalin. The uterus measures 7.6 SI x 4.7 ML x 3.1 cm AP with the cervix measuring 2.8 cm in diameter with a 1.2 cm slit-shaped os. The right and left ovary measures 1.9 x 1.1 x 0.6 cm and 1.8 x 0.8 x 0.6 cm respectively. The right and left fimbriated fallopian tube measures 3.0 cm in length by 0.4 cm in diameter and 4.5 cm in length by 0.4 cm in diameter respectively. The entire specimen weighs 85.8 g. On gross examination, the both the right and left ovary is tiny, with the external surface predominantly smooth, shiny and grossly unremarkable. On sectioning, the cut surface has a variegated brown tan color and has a slightly soft and flabby consistency. The right and left fimbriated fallopian tube is brown in color, predominantly smooth and grossly unremarkable. The anterior and posterior uterine serosa is brown tan in color, with focal areas of hemorrhagic fibrous adhesions with multiple defects noted predominantly seen on the anterior uterine serosa ranging in size from 0.5 to 2.1 cm in diameter. On sectioning, a large fungating polypoid tumor is identified predominantly adhered to the posterior endometrium measuring 3.1 SI x 3.5 ML x 2.8 cm AP. The tumor is brown-tan in color, and has a soft friable consistency. The rest of the endometrium has a nodular appearance. The myometrium has an average thickness of 1.0 cm and appears to be slightly trabeculated. A well circumscribed white-tan nodule with a whorled appearance is identified on the myometrium measuring 0.8 x 0.6 x 0.8 cm. The anterior and posterior endocervix is brown-tan in color with a defect of the the posterior cervix measuring 0.8 cm in maximum dimension. The exocervix appears to be slightly hemorrhagic. Representative sections are submitted as follows:

4A4B right fimbriated fallopian tube serially sectioned and submitted in toto

4C right ovary serially sectioned and submitted in toto

4D-4E left fallopian tube serially sectioned and submitted in toto

4F left ovary serially sectioned and submitted in toto

4G-4H anterior endomyometrium superior aspect full thickness

4I-4J anterior endomyometrium mid superior aspect to cervix to longitudinal section

4K additional representative section of the anterior endomyometrium to show nodularity in the endometrium

4L 4M posterior endomyometrium superior aspect full thickness

4N4O posterior endomyometrium mid superior aspect to cervix longitudinal section

4P additional representative section of the polypoid tumor taken from the posterior endomyometrium

Multiple pieces of tissue is stored frozen

Source: NCI Genomic Data Commons file 5af711aa-2704-41ab-afa0-9bd2a33dee7b (TCGA-EO-A3KW.C1CFE3DE-628B-4C0F-881B-588C613498DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).